Gene-level copy-number profile of specimen HCM-CSHL-0237-C18-85A from HCMI case HCM-CSHL-0237-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,416 days).
Specimen HCM-CSHL-0237-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 678b31b0-7a58-4114-b3fb-11e2f05d7556.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0237-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/ceaa60ab-f35e-43c1-8f64-de5b95e79303

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 137; copy number 2: 7,718; copy number 3: 33,334; copy number 4: 13,791; copy number 5: 2,033; copy number 6: 233; copy number 7: 1,103; copy number 10: 1; copy number 83: 1; copy number 149: 6; copy number 155: 4; copy number 163: 2; copy number 169: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,119 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:911,736–991,190, 2 genes, copy number 163 (within-gene range 4–163): RAD52, AC004803.1.
- chr12:4,247,981–4,405,490, 6 genes, copy number 149: CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23.
- chr12:17,066,368–17,400,914, 6 genes, copy number 155–169: AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1.
- chr12:17,710,934–17,711,046, 1 gene, copy number 83: Y_RNA.
- chr17:26,981,694–27,626,438, 19 genes, copy number 7 (within-gene range 5–7): AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1.
- chr17:27,798,806–28,855,232, 75 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr17:28,834,722–29,180,398, 23 genes, copy number 7: Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3.
- chr17:29,246,859–29,254,494, 1 gene, copy number 7: CRYBA1.
- chr17:29,340,482–29,930,276, 21 genes, copy number 7 (within-gene range 5–7): RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5.
- chr17:29,863,402–30,571,748, 33 genes, copy number 7: AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5, SLC6A4, AC104984.1, AC104984.4, SNORD63, BLMH, RNU6-1267P, TMIGD1, Y_RNA, RNU6-990P, CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3.
- chr17:30,702,504–30,702,775, 1 gene, copy number 7: RN7SL316P.
- chr17:30,830,901–31,575,659, 39 genes, copy number 7: AC127024.1, ATAD5, AC130324.2, RNU6-298P, AC130324.1, TEFM, AC130324.3, ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B.
- chr17:31,759,795–31,859,291, 4 genes, copy number 7: GPR160P2, AC007923.1, AC004253.2, COPRS.
- chr17:35,406,684–35,448,837, 5 genes, copy number 7: AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13.
- chr17:35,464,249–35,487,857, 1 gene, copy number 7 (within-gene range 5–7): SLFN12L.
- chr17:35,474,904–35,537,861, 1 gene, copy number 7 (within-gene range 5–7): SLFN12L.
- chr17:35,498,218–35,943,713, 32 genes, copy number 7: TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12, AP2B1, AC004134.1, TAF15, RASL10B, GAS2L2, MMP28, AC006237.1, C17orf50, AC015849.2, AC015849.3, AC015849.4, HEATR9, AC015849.6, AC015849.1, CCL5, 7SK, AC015849.5, LRRC37A9P, RDM1, LYZL6.
- chr17:39,023,394–39,053,205, 4 genes, copy number 7 (within-gene range 6–7): AC006441.5, LINC02079, LRRC37A11P, AC091178.1.
- chr17:39,156,894–39,402,523, 8 genes, copy number 7 (within-gene range 6–7): ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20.
- chr17:39,404,285–39,664,201, 8 genes, copy number 7 (within-gene range 6–7): MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3.
- chr17:39,671,122–39,877,896, 9 genes, copy number 7: PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr17:39,941,474–40,501,623, 33 genes, copy number 7: LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4.
- chr17:40,624,962–40,703,752, 6 genes, copy number 7: SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1, KRT24.
- chr20:30,278,906–55,684,915, 619 genes, copy number 7 (broad region; genes not listed).
- chr20:57,105,741–59,259,113, 62 genes, copy number 7 (broad region; genes not listed).
- chr20:61,953,469–62,577,507, 30 genes, copy number 7: TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1.
- chr20:63,240,784–64,327,972, 69 genes, copy number 7 (broad region; genes not listed).
- chr21:8,603,547–8,603,984, 1 gene, copy number 10: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
